Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A4UT, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A4UT-01A (Primary Tumor).

[page 1 of 2]
neck
J Neck

Additional Copy to:

Clinical Diagnosis & History:

Right nodule papillary thyroid cancer.

Specimens Submitted:

1: Total thyroid

DIAGNOSIS:

1. Total thyroid:

Part # 1

Tumor Type:

Papillary carcinoma, classical type
with focal oncocytic/tall cell features

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 1.0 cm.

Tumor Encapsulation:

None identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Microscopic foci present

Papillary microcarcinoma, 0.5 mm in greatest dimension (left lobe)

Adenoma(s) (away from the carcinoma):

Not identified

1CD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS 673.9

hw
10/27/12

[page 2 of 2]
Non-Neoplastic Thyroid:
Exhibits mild chronic lymphocytic thyroiditis
Parathyroid Glands:
Not identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled "Total thyroid", and consists of a thyroid weighing 8.5 g. The right lobe measures 3.5 x 2 x 0.8 cm, the left lobe measures 3 x 2 x 0.8 cm and the isthmus measures 1 x 1 x 0.4 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a nodule measuring 1.0 x 0.6 x 0.6 cm. The nodule is located in the middle lateral portion of the right lobe, displays white cut surfaces, and is not encapsulated. Sections through the remaining tissue reveal unremarkable cut surfaces. The remaining thyroid parenchyma is red brown and beefy. Representative sections of the specimen are submitted for TPS. The remainder of the specimen is entirely submitted for permanent histologic examination.

Summary of sections:

N - nodule, entirely submitted
RL - right lobe
LL - left lobe
IS - isthmus
ADDR - remainder of the right lobe
ADDL - remainder of the left lobe

Summary of Sections:

Part 1: Total thyroid

Block	Sect. Site	PCs
4	ADDL	4
3	ADDR	4
1	IS	0
1	LL	0
1	N	0
1	RL	0

10/27/12

Source: NCI Genomic Data Commons file 52776c70-8423-42e0-8213-dc80874911ef (TCGA-DJ-A4UT.02AD6E8E-1CEF-4BED-9236-B847EBF8513A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).